Somatic mutation profile of tumor specimen MMRF_1837_1_BM_CD138pos (aliquot MMRF_1837_1_BM_CD138pos_T1_KBS5U_L05550) from MMRF case MMRF_1837, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.6 years (22,119 days).
Specimen MMRF_1837_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f9aad97-4599-41d8-b02f-227eb49c9aa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1837_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1837_1_PB_Whole_C3_KBS5U_L05572; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df85e693-b650-424d-9d68-0753685d57f4

The open-access MAF lists 77 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 21, Silent 11, Intron 5, Frame Shift Del 3, 3'Flank 1, In Frame Del 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 50/113 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDX1 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1198504019; called by muse, mutect2, varscan2
- EPX | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs148158670, COSV99836648; called by muse, mutect2, varscan2
- FOXK1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 112/245 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1003844502, COSV61068538; called by muse, mutect2, varscan2
- IGHV2-70 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 49/54 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs549341348; called by muse, varscan2
- KALRN | c.2287A>T p.I763F | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as rs1421624620; called by muse, mutect2, varscan2
- MBD1 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757273205, COSV53274409, COSV53277796; called by muse, mutect2, varscan2
- NPAP1 | c.1981C>T p.L661F | Missense Mutation (SNP) | VAF 126/265 reads (48%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.721); catalogued as COSV61503903, COSV61512835; called by muse, mutect2, varscan2
- NPAP1 | c.2411C>G p.S804C | Missense Mutation (SNP) | VAF 123/261 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.545); catalogued as COSV100275376, COSV61507080; called by muse, mutect2, varscan2
- NPTX2 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1370330709, COSV55717447; called by muse, mutect2, varscan2
- OR1A2 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs775857630, COSV67936143; called by muse, mutect2, varscan2
- TLN2 | c.6011C>T p.T2004M | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs748278928, COSV60896214; called by muse, mutect2, varscan2
- ASCC1 | c.140G>C p.C47S | Missense Mutation (SNP) | VAF 169/371 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ASMT | c.268T>C p.S90P | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0.05); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CDH18 | c.976_983del p.E326Pfs*10 | Frame Shift Del (DEL) | VAF 33/78 reads (42%) | called by mutect2, pindel, varscan2
- CENPE | c.3510del p.E1171Nfs*2 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- DIS3 | c.2450T>G p.L817R | Missense Mutation (SNP) | VAF 136/154 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- DISP3 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- DSP | c.3050T>C p.L1017S | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EDNRA | c.1154G>A p.C385Y | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ELAC2 | c.1894T>A p.C632S | Missense Mutation (SNP) | VAF 96/154 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENGASE | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- GJA1 | c.830C>G p.P277R | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- H2AC11 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- IGHV3-33 | c.42A>T p.L14F | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.045); called by muse, varscan2
- KIAA1217 | c.3419T>C p.F1140S | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- LRRC53 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5AK2 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT tolerated (1); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PADI1 | c.1893T>G p.D631E | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PCBP1 | c.788G>A p.S263N | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PSD2 | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by mutect2, varscan2
- PTPN4 | c.1700_1711del p.V567_N570del | In Frame Del (DEL) | VAF 88/210 reads (42%) | called by mutect2, pindel, varscan2
- SEMA5B | c.2974C>T p.L992F | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TNC | c.4685_4694del p.T1562Ifs*26 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | called by mutect2, pindel, varscan2
- TRIM29 | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF609 | c.2924A>G p.N975S | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZSWIM2 | c.1112T>A p.I371N | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CALML4 | c.294C>A p.T98= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- COL11A1 | c.3513T>A p.G1171= | Silent (SNP) | VAF 55/131 reads (42%) | called by muse, mutect2, varscan2
- FBXO42 | c.672G>C p.V224= | Silent (SNP) | VAF 72/154 reads (47%) | called by muse, mutect2, varscan2
- IGLV4-69 | c.297C>T p.I99= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as rs766178020; called by muse, varscan2
- LYVE1 | c.105A>G p.S35= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as rs372396648; called by muse, mutect2, varscan2
- SPTBN5 | c.9972G>A p.Q3324= | Silent (SNP) | VAF 74/159 reads (47%) | called by muse, mutect2, varscan2
- TBX18 | c.1539C>A p.T513= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV63736898; called by muse, mutect2, varscan2
- TP63 | c.417G>A p.A139= | Silent (SNP) | VAF 239/402 reads (59%) | catalogued as rs575351974; called by muse, mutect2, varscan2
- TRIM9 | c.1929A>G p.K643= | Silent (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- TSHZ1 | c.3213G>C p.V1071= (on ENST00000580243 / NM_001308210.2; = p.V1026= on NM_005786.6) | Silent (SNP) | VAF 51/121 reads (42%) | called by muse, mutect2, varscan2
- ZBTB7A | c.1332C>T p.G444= | Silent (SNP) | VAF 129/263 reads (49%) | catalogued as rs757689355, COSV100475887, COSV100475977; called by muse, mutect2, varscan2
- ACOXL | c.789-21368C>T | Intron (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- ARFRP1 | c.*476G>T | 3'UTR (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2, varscan2
- BEND4 | c.*2802G>C | 3'UTR (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- BMPR2 | c.*1963G>T | 3'UTR (SNP) | VAF 44/130 reads (34%) | called by muse, mutect2, varscan2
- BTN3A3 | c.*21A>C | 3'UTR (SNP) | VAF 129/286 reads (45%) | called by muse, mutect2, varscan2
- C21orf91 | c.*3026T>C | 3'UTR (SNP) | VAF 60/121 reads (50%) | called by muse, mutect2, varscan2
- CASZ1 | c.*1043G>A | 3'UTR (SNP) | VAF 52/116 reads (45%) | catalogued as rs956134924; called by muse, mutect2, varscan2
- COLEC10 | c.*206G>A | 3'UTR (SNP) | VAF 45/87 reads (52%) | catalogued as rs535589887; called by muse, mutect2, varscan2
- DPP10 | c.*1804G>T | 3'UTR (SNP) | VAF 64/125 reads (51%) | catalogued as rs942680552; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+2158C>G | Intron (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.240-18166C>T | Intron (SNP) | VAF 28/54 reads (52%) | catalogued as rs768420916; called by muse, mutect2, varscan2
- MYCT1 | c.*653A>T | 3'UTR (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- OR4K13 | c.*56G>A | 3'UTR (SNP) | VAF 77/148 reads (52%) | catalogued as rs564711676; called by muse, mutect2, varscan2
- PCDH11X | c.*704T>A | 3'UTR (SNP) | VAF 170/185 reads (92%) | called by muse, mutect2, varscan2
- PCDH11Y | c.*704T>A | 3'UTR (SNP) | VAF 21/26 reads (81%) | called by mutect2, varscan2
- PLCXD3 | c.*6086T>A | 3'UTR (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.-24C>T | 5'UTR (SNP) | VAF 57/142 reads (40%) | catalogued as COSV99770366; called by muse, mutect2, varscan2
- ROBO2 | c.3136+534C>A | Intron (SNP) | VAF 97/169 reads (57%) | called by muse, mutect2, varscan2
- S100A7A | chr1:153422091 C>A | 3'Flank (SNP) | VAF 108/243 reads (44%) | called by muse, mutect2, varscan2
- S1PR3 | c.*394G>T | 3'UTR (SNP) | VAF 73/158 reads (46%) | called by muse, mutect2, varscan2
- SERF2 | c.*1558T>C | 3'UTR (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- SLC25A53 | c.*973C>A | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
- SOX11 | c.*3995A>T | 3'UTR (SNP) | VAF 5/93 reads (5%) | catalogued as COSV58983565; called by muse, mutect2
- SYT9 | c.*304G>C | 3'UTR (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- TMEM154 | c.*8309A>G | 3'UTR (SNP) | VAF 64/140 reads (46%) | called by muse, mutect2, varscan2
- TMEM273 | c.294-83G>T | Intron (SNP) | VAF 186/451 reads (41%) | catalogued as rs1451276717; called by muse, mutect2, varscan2
- TTBK1 | c.*891C>A | 3'UTR (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- ZIC1 | c.*2468G>C | 3'UTR (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- ZNRD2 | chr11:65570123 G>A | 5'Flank (SNP) | VAF 51/113 reads (45%) | called by muse, mutect2, varscan2
